Somatic mutation profile of tumor specimen TCGA-EL-A3H7-01A (aliquot TCGA-EL-A3H7-01A-11D-A21A-08) from TCGA case TCGA-EL-A3H7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.7 years (13,407 days).
Specimen TCGA-EL-A3H7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25b2a081-0d6a-46ec-8312-f9c753e77635.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3H7-11A (Solid Tissue Normal), aliquot TCGA-EL-A3H7-11A-11D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/776524ad-c974-437c-ba40-f9ce46cf5635

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- ABHD4 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV53529555; called by muse, mutect2
- FAM120C | c.609C>A p.N203K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs144201658, COSV60258616; called by muse, mutect2, varscan2
- HHLA2 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as rs369237811; called by muse, mutect2, varscan2
- IFNAR2 | c.930G>C p.K310N | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51614924; called by muse, mutect2, varscan2
- INPP5F | c.2569T>C p.S857P | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62820669; called by muse, mutect2, varscan2
- MUC5B | c.16768G>A p.A5590T | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs751528862, COSV71591254; called by muse, mutect2
- PCDHA8 | c.1853C>G p.P618R | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs369930708, COSV65325287; called by muse, mutect2
- PEX10 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1430139842, COSV56580014; called by muse, mutect2
- RNF216 | c.2428C>A p.P810T (on ENST00000425013 / NM_207116.3; = p.P867T on NM_207111.4) | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV66290027; called by muse, mutect2, varscan2
- SERPINE3 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV68545136; called by muse, mutect2, varscan2
- SETBP1 | c.1338A>T p.E446D | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56318441; called by muse, mutect2
- TAS1R2 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs577863777, COSV64744370; called by muse, mutect2, varscan2
- TM9SF4 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.577); catalogued as COSV54106060; called by muse, mutect2, varscan2
- TTLL5 | c.3010C>T p.H1004Y | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.368); catalogued as COSV54031187; called by muse, mutect2, varscan2
- FAM217A | c.1246_1249del p.F416Nfs*33 | Frame Shift Del (DEL) | VAF 41/152 reads (27%) | called by mutect2, pindel, varscan2
- BRD3 | c.588C>T p.I196= | Silent (SNP) | VAF 23/322 reads (7%) | catalogued as rs142203601; called by muse, mutect2
- GPT | c.1281C>T p.R427= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1459622845, COSV52952743; called by muse, mutect2
- INTS2 | c.783C>G p.A261= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as COSV52152272; called by muse, mutect2
- ZNF41 | c.1092T>C p.F364= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV57442040; called by muse, mutect2, varscan2
